Somatic mutation profile of tumor specimen TCGA-21-1077-01A (aliquot TCGA-21-1077-01A-01W-0782-08) from TCGA case TCGA-21-1077, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 64.4 years (23,523 days).
Specimen TCGA-21-1077-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f461d4d5-e1a0-42b6-b737-1fcc02759381.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-21-1077-11A (Solid Tissue Normal), aliquot TCGA-21-1077-11A-01D-1521-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/68be9701-ea94-4380-81ef-89dcd5f6ef8e

The open-access MAF lists 239 somatic variants for this specimen: 178 protein-altering or splice-affecting, 57 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 141, Silent 57, Nonsense Mutation 18, Frame Shift Del 9, Splice Site 4, Frame Shift Ins 4, Splice Region 2, RNA 2, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RHAG | c.1067+1G>A p.X356_splice | Splice Site (SNP) | VAF 32/190 reads (17%) | catalogued as rs1562012617, CS982347, COSV57703785; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.375G>T p.T125= | Splice Region (SNP) | VAF 168/407 reads (41%) | catalogued as rs55863639, CS004351, CS011573, CS971913, COSV52665709, COSV52718605, COSV52726641, COSV53120615; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- AAAS | c.108dup p.D37Rfs*50 | Frame Shift Ins (INS) | VAF 6/54 reads (11%) | catalogued as rs767120429; called by mutect2, pindel
- ABCA9 | c.3126G>A p.M1042I | Missense Mutation (SNP) | VAF 45/339 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.483); catalogued as COSV100382816; called by muse, mutect2, varscan2
- ACSM2B | c.1615A>T p.K539* | Nonsense Mutation (SNP) | VAF 55/297 reads (19%) | catalogued as COSV61658552; called by muse, mutect2, varscan2
- ACSM4 | c.1675C>T p.L559F | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV68068255; called by muse, mutect2, varscan2
- ADAMTS6 | c.2709G>A p.W903* | Nonsense Mutation (SNP) | VAF 45/286 reads (16%) | catalogued as COSV58683848, COSV58685618; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2442T>A p.C814* | Nonsense Mutation (SNP) | VAF 16/314 reads (5%) | catalogued as COSV54454818; called by muse, mutect2
- AFF3 | c.1920G>C p.E640D | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as COSV57858936, COSV57873176; called by muse, mutect2, varscan2
- AGPAT3 | c.212C>T p.T71M | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.374); catalogued as rs200808478, COSV52371469; called by muse, mutect2, varscan2
- ANKRD7 | c.436G>T p.E146* | Nonsense Mutation (SNP) | VAF 42/102 reads (41%) | catalogued as COSV54555385; called by muse, mutect2, varscan2
- ANKS1B | c.2397A>C p.K799N | Missense Mutation (SNP) | VAF 30/176 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV61358985; called by muse, mutect2, varscan2
- APBA2 | c.152T>C p.L51P | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.161); catalogued as COSV68792516; called by muse, mutect2, varscan2
- AQR | c.923A>G p.Y308C | Missense Mutation (SNP) | VAF 114/301 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); catalogued as COSV50038605; called by muse, mutect2, varscan2
- ARHGAP21 | c.4664A>G p.Q1555R | Missense Mutation (SNP) | VAF 36/246 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV57607425; called by muse, mutect2, varscan2
- ARMC5 | c.412G>T p.D138Y | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as COSV51657632, COSV99192346; called by muse, mutect2, varscan2
- ATP4B | c.520G>T p.E174* | Nonsense Mutation (SNP) | VAF 10/42 reads (24%) | catalogued as COSV58929242; called by muse, mutect2, varscan2
- BACH1 | c.453G>T p.Q151H | Missense Mutation (SNP) | VAF 25/199 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as COSV54519590; called by muse, mutect2, varscan2
- BCAR1 | c.397C>A p.P133T | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.033); catalogued as COSV50787573; called by muse, mutect2, varscan2
- BIRC6 | c.14171C>T p.S4724F | Missense Mutation (SNP) | VAF 97/730 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70201748; called by muse, mutect2, varscan2
- C1orf94 | c.631C>G p.L211V (on ENST00000488417 / NM_001134734.2; = p.L21V on NM_032884.5) | Missense Mutation (SNP) | VAF 63/286 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.52); catalogued as COSV64914439; called by muse, mutect2, varscan2
- CAMTA2 | c.1443G>T p.R481S | Missense Mutation (SNP) | VAF 94/201 reads (47%) | SIFT tolerated, low confidence (0.21); PolyPhen probably damaging (0.942); catalogued as COSV61835763; called by muse, mutect2, varscan2
- CBLIF | c.280C>A p.L94I | Missense Mutation (SNP) | VAF 24/213 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV57239427; called by muse, mutect2, varscan2
- CCDC180 | c.3708G>C p.Q1236H | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.824); catalogued as COSV63831735; called by muse, mutect2, varscan2
- CCDC73 | c.1015G>C p.E339Q | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV58800525; called by muse, varscan2
- CD101 | c.2134A>T p.I712F | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.541); catalogued as COSV56718983; called by muse, mutect2, varscan2
- CHRNB4 | c.77C>A p.A26E | Missense Mutation (SNP) | VAF 108/505 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.769); catalogued as rs771105669, COSV55717289, COSV99929256; called by mutect2, varscan2
- CMYA5 | c.8614C>T p.H2872Y | Missense Mutation (SNP) | VAF 48/615 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.276); catalogued as COSV71407000; called by muse, mutect2
- CNTN3 | c.809C>T p.S270F | Missense Mutation (SNP) | VAF 16/198 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.696); catalogued as COSV55163859; called by muse, mutect2
- COL7A1 | c.6393+1G>A p.X2131_splice | Splice Site (SNP) | VAF 14/31 reads (45%) | catalogued as COSV60395896, COSV60397362; called by muse, mutect2, varscan2
- CPS1 | c.1268C>T p.S423F | Missense Mutation (SNP) | VAF 51/273 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV51814548; called by muse, mutect2, varscan2
- CTNNA3 | c.2401-2A>G p.X801_splice | Splice Site (SNP) | VAF 38/194 reads (20%) | catalogued as COSV101041287; called by muse, mutect2, varscan2
- CTNNB1 | c.2141C>G p.P714R | Missense Mutation (SNP) | VAF 93/245 reads (38%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.209); catalogued as COSV100846291, COSV62705613; called by muse, mutect2, varscan2
- CYP11B1 | c.872C>T p.A291V | Missense Mutation (SNP) | VAF 76/125 reads (61%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.71); catalogued as rs1193417504, COSV52828390; called by muse, mutect2, varscan2
- DDX58 | c.76C>A p.L26M | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as COSV65883683; called by muse, mutect2, varscan2
- DIAPH1 | c.2474-2A>T p.X825_splice | Splice Site (SNP) | VAF 55/231 reads (24%) | catalogued as COSV99526085; called by muse, mutect2, varscan2
- DNMT1 | c.2507A>T p.Y836F | Missense Mutation (SNP) | VAF 232/578 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.082); catalogued as COSV61580650; called by muse, varscan2
- EIF6 | c.65C>T p.T22I | Missense Mutation (SNP) | VAF 79/264 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as COSV65583526; called by muse, mutect2, varscan2
- EPHA3 | c.205del p.Q69Rfs*14 | Frame Shift Del (DEL) | VAF 18/88 reads (20%) | catalogued as COSV60703506; called by mutect2, pindel, varscan2
- ESAM | c.737G>T p.G246V | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.192); catalogued as COSV54035557; called by muse, mutect2, varscan2
- F13A1 | c.1808C>G p.A603G | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV53561205; called by muse, mutect2, varscan2
- FAM135B | c.2051C>G p.S684C | Missense Mutation (SNP) | VAF 35/224 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52734599, COSV52752032; called by muse, mutect2, varscan2
- FBXL7 | c.1426C>T p.R476C | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs1275721257, COSV61648197; called by muse, mutect2, varscan2
- FNIP1 | c.1120A>G p.M374V | Missense Mutation (SNP) | VAF 91/248 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.171); catalogued as rs551838274, COSV57197745; called by muse, mutect2, varscan2
- FOXI1 | c.718G>T p.V240L | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV60389013; called by muse, mutect2, varscan2
- FOXR2 | c.298G>A p.G100R | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as rs774657036, COSV59258953; called by muse, mutect2, varscan2
- GATA3 | c.1304C>G p.P435R | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.298); catalogued as COSV60520066; called by muse, mutect2, varscan2
- GDF2 | c.627C>A p.S209R | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.033); catalogued as rs374479283; called by muse, mutect2, varscan2
- GEN1 | c.2590G>T p.E864* | Nonsense Mutation (SNP) | VAF 11/88 reads (13%) | catalogued as COSV58057270; called by muse, mutect2, varscan2
- GFRAL | c.682C>A p.Q228K | Missense Mutation (SNP) | VAF 38/274 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.02); catalogued as COSV61230166, COSV61232343; called by muse, mutect2, varscan2
- GJA5 | c.709C>T p.R237* | Nonsense Mutation (SNP) | VAF 5/75 reads (7%) | catalogued as rs1476854402, COSV54784896; called by muse, mutect2
- GPRIN1 | c.145C>G p.Q49E | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.637); catalogued as COSV56140877, COSV99992254; called by muse, mutect2, varscan2
- GRIN3A | c.2371G>T p.G791* | Nonsense Mutation (SNP) | VAF 27/153 reads (18%) | catalogued as COSV62455498; called by muse, mutect2, varscan2
- GTF2H4 | c.17C>A p.S6* | Nonsense Mutation (SNP) | VAF 13/132 reads (10%) | catalogued as COSV52559653; called by muse, mutect2, varscan2
- HCN3 | c.1168C>T p.H390Y | Missense Mutation (SNP) | VAF 88/188 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.311); catalogued as COSV64234464; called by muse, mutect2, varscan2
- HIGD1A | c.130G>A p.G44R | Missense Mutation (SNP) | VAF 16/173 reads (9%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.651); catalogued as COSV58415126; called by muse, mutect2
- IDI1 | c.318A>T p.L106F | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as COSV67281739; called by muse, mutect2, varscan2
- IGLV6-57 | c.292T>A p.S98T | Missense Mutation (SNP) | VAF 35/182 reads (19%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.035); catalogued as COSV66504160; called by muse, mutect2, varscan2
- ITGA8 | c.389T>A p.F130Y | Missense Mutation (SNP) | VAF 51/262 reads (19%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.995); catalogued as COSV65231066; called by muse, mutect2, varscan2
- ITGB8 | c.1383T>G p.I461M | Missense Mutation (SNP) | VAF 9/164 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV56010553; called by muse, mutect2
- KBTBD3 | c.203G>T p.C68F | Missense Mutation (SNP) | VAF 13/147 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV73241496; called by muse, mutect2, varscan2
- KCNJ3 | c.969G>T p.W323C | Missense Mutation (SNP) | VAF 27/164 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99715439; called by muse, mutect2, varscan2
- KRT72 | c.1457G>C p.G486A | Missense Mutation (SNP) | VAF 107/850 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as COSV53374978; called by muse, mutect2, varscan2
- LCP1 | c.487del p.L163Ffs*4 | Frame Shift Del (DEL) | VAF 66/315 reads (21%) | catalogued as COSV59941524; called by mutect2, pindel, varscan2
- LCT | c.2219C>T p.S740F | Missense Mutation (SNP) | VAF 38/171 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.202); catalogued as rs753715951, COSV51552283; called by muse, mutect2, varscan2
- LPIN2 | c.1175A>G p.H392R | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV55240965; called by muse, mutect2, varscan2
- LUC7L3 | c.79G>T p.V27L | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.991); catalogued as COSV53587817; called by mutect2, varscan2
- MARCHF6 | c.1874G>T p.R625L | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV56883219; called by muse, mutect2, varscan2
- MB21D2 | c.931C>G p.Q311E | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.403); catalogued as rs988241015, COSV66661548, COSV66661553; called by muse, mutect2, varscan2
- MEIOB | c.1268C>T p.S423L | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs771416758, COSV58054616; called by muse, mutect2, varscan2
- MEIOC | c.856G>C p.D286H | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372645745, COSV63440066; called by muse, mutect2, varscan2
- MIDEAS | c.2612A>T p.Y871F | Missense Mutation (SNP) | VAF 166/351 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54095882; called by muse, mutect2, varscan2
- MUTYH | c.1208C>T p.S403F | Missense Mutation (SNP) | VAF 75/153 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as rs559963863, COSV58343437; called by muse, mutect2, varscan2
- MYH10 | c.326A>G p.Y109C | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52604383; called by muse, mutect2
- MYH7B | c.1355A>C p.N452T | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV53421709; called by muse, mutect2, varscan2
- MYO1D | c.2948C>T p.T983M | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.714); catalogued as rs745881728, COSV57831300; called by muse, varscan2
- NAIF1 | c.81G>C p.K27N | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT tolerated (0.96); PolyPhen benign (0.028); catalogued as COSV66091315; called by muse, mutect2, varscan2
- NEB | c.4342G>A p.G1448R | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200002537, COSV51429406; called by muse, mutect2, varscan2
- NUAK1 | c.401A>G p.Y134C | Missense Mutation (SNP) | VAF 56/393 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs557272627, COSV54604706; called by muse, mutect2, varscan2
- NUP188 | c.972G>T p.L324F | Missense Mutation (SNP) | VAF 76/349 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65363096; called by muse, mutect2, varscan2
- NUTM2G | c.1132G>T p.E378* | Nonsense Mutation (SNP) | VAF 24/104 reads (23%) | catalogued as COSV63617458; called by muse, varscan2
- NUTM2G | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.381); catalogued as COSV63617463; called by muse, varscan2
- OLFM3 | c.80C>A p.P27Q | Missense Mutation (SNP) | VAF 154/353 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV58800407; called by muse, mutect2, varscan2
- OR2B11 | c.185C>A p.P62H | Missense Mutation (SNP) | VAF 358/709 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100275756, COSV100276452, COSV59510571; called by muse, mutect2, varscan2
- OR51B2 | c.838C>A p.L280I | Missense Mutation (SNP) | VAF 124/289 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.654); catalogued as COSV60917032; called by muse, mutect2, varscan2
- OR5L1 | c.732C>A p.H244Q | Missense Mutation (SNP) | VAF 17/260 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs145975508; called by muse, mutect2
- OR5L1 | c.733C>A p.L245I | Missense Mutation (SNP) | VAF 19/260 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as rs770995985, COSV61734405; called by muse, mutect2
- OR8D1 | c.727T>A p.S243T | Missense Mutation (SNP) | VAF 27/285 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200813687; called by muse, mutect2
- OR8G5 | c.495G>T p.R165S | Missense Mutation (SNP) | VAF 171/589 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.472); catalogued as rs1307402693, COSV100422296, COSV100422531; called by muse, mutect2, varscan2
- PARP11 | c.415C>T p.Q139* | Nonsense Mutation (SNP) | VAF 28/174 reads (16%) | catalogued as COSV57395798; called by muse, mutect2, varscan2
- PATJ | c.109A>G p.M37V | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs564523661, COSV57165329; called by muse, mutect2, varscan2
- PCDH15 | c.3580G>T p.G1194* | Nonsense Mutation (SNP) | VAF 85/425 reads (20%) | catalogued as COSV57316728, COSV57342928; called by muse, mutect2, varscan2
- PCDH17 | c.1513G>A p.G505S | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); catalogued as COSV64975625; called by muse, mutect2, varscan2
- PCDHB12 | c.1402C>A p.L468M | Missense Mutation (SNP) | VAF 31/149 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.777); catalogued as COSV99506983; called by muse, mutect2, varscan2
- PCDHGB2 | c.586C>G p.L196V | Missense Mutation (SNP) | VAF 9/136 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.381); catalogued as COSV53903069, COSV53974436; called by muse, mutect2
- PDXDC1 | c.528A>G p.I176M | Missense Mutation (SNP) | VAF 19/140 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs1355362811, COSV57908633; called by muse, mutect2, varscan2
- PHEX | c.277C>G p.P93A | Missense Mutation (SNP) | VAF 64/177 reads (36%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.966); catalogued as COSV65076601; called by muse, mutect2, varscan2
- PIGG | c.1976G>A p.W659* (on ENST00000453061 / NM_001127178.3; = p.W651* on NM_017733.4) | Nonsense Mutation (SNP) | VAF 5/14 reads (36%) | catalogued as COSV56319114, COSV56320609; called by muse, mutect2, varscan2
- POLR3E | c.838G>C p.D280H | Missense Mutation (SNP) | VAF 23/138 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55401592; called by muse, mutect2, varscan2
- PROX1 | c.709C>T p.R237* | Nonsense Mutation (SNP) | VAF 109/150 reads (73%) | catalogued as COSV54780655; called by muse, mutect2, varscan2
- RELN | c.6871C>T p.L2291F | Missense Mutation (SNP) | VAF 33/148 reads (22%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.466); catalogued as COSV59003702, COSV59010623; called by muse, mutect2, varscan2
- RELN | c.3286C>G p.Q1096E | Missense Mutation (SNP) | VAF 38/297 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV58996045; called by muse, mutect2, varscan2
- RELN | c.1296T>G p.D432E | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as COSV59012486; called by muse, mutect2, varscan2
- RGL1 | c.972T>G p.N324K (on ENST00000360851 / NM_001297672.2; = p.N359K on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 55/368 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58988381; called by muse, mutect2, varscan2
- RIPOR3 | c.2557C>T p.R853W | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs371046060; called by muse, varscan2
- ROBO3 | c.3296G>T p.G1099V | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.368); catalogued as rs1347678858, COSV67301263; called by muse, mutect2, varscan2
- ROCK1 | c.3299C>G p.S1100C | Missense Mutation (SNP) | VAF 83/426 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as COSV101296620, COSV67696837; called by muse, mutect2, varscan2
- RTTN | c.1918G>T p.E640* | Nonsense Mutation (SNP) | VAF 22/75 reads (29%) | catalogued as COSV55347433; called by muse, mutect2, varscan2
- RYR2 | c.5174A>T p.Y1725F | Missense Mutation (SNP) | VAF 128/260 reads (49%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV63693758; called by muse, varscan2
- RYR2 | c.5237A>G p.H1746R | Missense Mutation (SNP) | VAF 24/200 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.311); catalogued as COSV63693762; called by muse, varscan2
- RYR2 | c.9832G>C p.G3278R | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.889); catalogued as COSV63693767; called by muse, mutect2, varscan2
- SCAPER | c.1798C>T p.H600Y | Missense Mutation (SNP) | VAF 173/814 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as COSV57743556; called by muse, mutect2, varscan2
- SHLD1 | c.164C>G p.S55C | Missense Mutation (SNP) | VAF 49/242 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.948); catalogued as COSV57437445; called by muse, mutect2, varscan2
- SLC16A10 | c.556C>A p.P186T | Missense Mutation (SNP) | VAF 17/140 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64354711; called by muse, mutect2, varscan2
- SLC25A36 | c.651A>C p.E217D | Missense Mutation (SNP) | VAF 51/135 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs772045480, COSV60782349; called by muse, mutect2, varscan2
- SLC45A2 | c.290C>G p.S97C | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.05); catalogued as COSV56872959; called by muse, mutect2, varscan2
- SLCO6A1 | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 30/208 reads (14%) | SIFT tolerated (0.69); PolyPhen benign (0.005); catalogued as rs1267598371, COSV65805369; called by muse, mutect2, varscan2
- SLITRK3 | c.675G>A p.M225I | Missense Mutation (SNP) | VAF 30/411 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV53849448; called by muse, mutect2
- SNAP91 | c.766C>A p.Q256K | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.555); catalogued as COSV52126234; called by muse, mutect2, varscan2
- SOS1 | c.1772A>G p.N591S | Missense Mutation (SNP) | VAF 23/154 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.041); catalogued as rs757213444, COSV67676173; ClinVar: benign; called by muse, mutect2, varscan2
- SPARCL1 | c.1302G>C p.M434I | Missense Mutation (SNP) | VAF 7/124 reads (6%) | SIFT tolerated (0.44); PolyPhen benign (0.009); catalogued as COSV56805376; called by muse, mutect2
- SPATA31D1 | c.798G>T p.L266F | Missense Mutation (SNP) | VAF 151/1205 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV61197696; called by muse, mutect2, varscan2
- SPHKAP | c.3182C>T p.A1061V | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as rs778910801, COSV60869051; called by muse, mutect2, varscan2
- SPTBN1 | c.6722A>C p.K2241T | Missense Mutation (SNP) | VAF 90/400 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61690069; called by muse, mutect2, varscan2
- STIP1 | c.1196A>G p.N399S | Missense Mutation (SNP) | VAF 104/321 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780822146, COSV59439160; called by muse, mutect2, varscan2
- STRBP | c.761G>A p.C254Y | Missense Mutation (SNP) | VAF 61/348 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.968); catalogued as COSV62118793; called by muse, mutect2, varscan2
- SYNE1 | c.22594G>C p.E7532Q (on ENST00000367255 / NM_182961.4; = p.E7461Q on NM_033071.3) | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV55020484, COSV55051805; called by muse, mutect2, varscan2
- TDRD6 | c.970G>T p.G324* | Nonsense Mutation (SNP) | VAF 19/53 reads (36%) | catalogued as COSV60176607; called by muse, mutect2, varscan2
- TECTA | c.5453G>T p.C1818F | Missense Mutation (SNP) | VAF 35/257 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50732407; called by muse, mutect2, varscan2
- TENM4 | c.7091G>T p.G2364V | Missense Mutation (SNP) | VAF 86/218 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53640776; called by muse, mutect2, varscan2
- TFB1M | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.013); catalogued as COSV51641827; called by muse, mutect2, varscan2
- THOC3 | c.779G>T p.R260L | Missense Mutation (SNP) | VAF 17/180 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV99442003, COSV99442041; called by muse, mutect2, varscan2
- TMCC3 | c.716A>T p.Y239F | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.446); catalogued as rs762511692, COSV54155338; called by muse, mutect2, varscan2
- TOR1B | c.932T>C p.M311T | Missense Mutation (SNP) | VAF 35/141 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as rs201490031, COSV52213736; called by muse, mutect2, varscan2
- TPK1 | c.169G>C p.E57Q | Missense Mutation (SNP) | VAF 122/807 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.022); catalogued as COSV63642838; called by muse, mutect2, varscan2
- TRANK1 | c.4130T>G p.L1377R | Missense Mutation (SNP) | VAF 232/700 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57154511; called by muse, varscan2
- TRAPPC9 | c.2401del p.Q801Rfs*15 | Frame Shift Del (DEL) | VAF 32/206 reads (16%) | catalogued as COSV101226593; called by pindel, varscan2
- TRIM42 | c.1722C>A p.Y574* | Nonsense Mutation (SNP) | VAF 46/239 reads (19%) | catalogued as COSV53884263; called by muse, mutect2, varscan2
- TRPC4 | c.220C>A p.L74I | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58996418, COSV59005054; called by muse, mutect2, varscan2
- TSHZ3 | c.3005G>T p.R1002L | Missense Mutation (SNP) | VAF 37/142 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.982); catalogued as COSV53684808, COSV99550988; called by muse, mutect2, varscan2
- TSKS | c.1712G>A p.G571E | Missense Mutation (SNP) | VAF 129/298 reads (43%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.79); catalogued as rs868763430, COSV55876225; called by muse, mutect2, varscan2
- TTBK2 | c.3284A>G p.Y1095C | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs199727474, COSV51165891; called by muse, mutect2, varscan2
- TTC21B | c.802A>T p.T268S | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54632053; called by muse, mutect2, varscan2
- TTN | c.2207G>A p.G736E (on ENST00000591111; = p.G690E on NM_003319.4) | Missense Mutation (SNP) | VAF 7/96 reads (7%) | PolyPhen benign (0.027); catalogued as rs1420857110, COSV59939195; called by muse, mutect2
- TUFM | c.851G>C p.R284P | Missense Mutation (SNP) | VAF 31/165 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV57948554, COSV57949231; called by muse, mutect2, varscan2
- TXLNB | c.1775G>A p.G592D | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.006); catalogued as COSV64444582; called by muse, varscan2
- TXLNB | c.38G>A p.R13Q | Missense Mutation (SNP) | VAF 11/140 reads (8%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); catalogued as rs754390761; called by muse, mutect2
- USH2A | c.976G>A p.D326N | Missense Mutation (SNP) | VAF 79/226 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100240574, COSV56390686; called by muse, mutect2, varscan2
- USP13 | c.1844G>T p.R615L | Missense Mutation (SNP) | VAF 44/996 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55867131; called by muse, mutect2
- USP54 | c.1159A>G p.I387V | Missense Mutation (SNP) | VAF 33/209 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV60444227; called by muse, mutect2, varscan2
- UTP14C | c.1741G>C p.E581Q | Missense Mutation (SNP) | VAF 59/255 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.048); catalogued as COSV73000719; called by muse, mutect2, varscan2
- UTRN | c.2527C>A p.R843= | Splice Region (SNP) | VAF 22/57 reads (39%) | catalogued as COSV62339448; called by muse, mutect2, varscan2
- WDR33 | c.3664G>A p.G1222S | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.998); catalogued as COSV59251436; called by muse, mutect2, varscan2
- ZC3H12B | c.1627C>A p.H543N | Missense Mutation (SNP) | VAF 90/136 reads (66%) | SIFT tolerated (0.31); PolyPhen benign (0.272); catalogued as COSV59049406; called by muse, mutect2, varscan2
- ZCCHC14 | c.2741C>G p.T914S (on ENST00000268616; = p.T1051S on NM_015144.3) | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as COSV51887543; called by muse, varscan2
- ZFY | c.466A>T p.S156C | Missense Mutation (SNP) | VAF 124/294 reads (42%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.591); catalogued as COSV50083590; called by muse, mutect2, varscan2
- ZIC1 | c.635C>A p.A212D | Missense Mutation (SNP) | VAF 69/100 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs752213758, COSV51555196; called by muse, mutect2, varscan2
- ZNF257 | c.1393G>T p.G465C | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV71306197; called by muse, mutect2, varscan2
- ZNF444 | c.358G>T p.G120C | Missense Mutation (SNP) | VAF 52/110 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV61363630; called by muse, mutect2, varscan2
- ZNF462 | c.7017C>A p.H2339Q | Missense Mutation (SNP) | VAF 59/405 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.011); catalogued as COSV52943608; called by muse, mutect2, varscan2
- ZNF692 | c.125A>G p.K42R | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as rs760655992, COSV60659731; called by muse, mutect2, varscan2
- ZSCAN18 | c.392T>C p.L131P | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as COSV53734310; called by muse, mutect2, varscan2
- ZSCAN5B | c.1390G>T p.E464* | Nonsense Mutation (SNP) | VAF 30/135 reads (22%) | catalogued as COSV62000486; called by muse, mutect2, varscan2
- ZSCAN5B | c.776A>G p.K259R | Missense Mutation (SNP) | VAF 81/357 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.265); catalogued as COSV62000491; called by muse, mutect2, varscan2
- AL592490.1 | c.2123_2127del p.Y708Ffs*4 | Frame Shift Del (DEL) | VAF 63/371 reads (17%) | called by mutect2, pindel, varscan2
- C12orf4 | c.677G>T p.W226L | Missense Mutation (SNP) | VAF 49/281 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- CARD6 | c.1367C>T p.S456F | Missense Mutation (SNP) | VAF 37/443 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DNAJB5 | c.873del p.C292Afs*10 | Frame Shift Del (DEL) | VAF 32/307 reads (10%) | called by mutect2, varscan2
- GIN1 | c.909dup p.E304* | Frame Shift Ins (INS) | VAF 38/270 reads (14%) | called by mutect2, pindel, varscan2
- HP | c.1032del p.K345Sfs*31 | Frame Shift Del (DEL) | VAF 78/398 reads (20%) | called by mutect2, varscan2
- IGKV1-6 | c.85T>A p.S29T | Missense Mutation (SNP) | VAF 77/361 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- KIAA0930 | c.460G>A p.E154K (on ENST00000336156 / NM_001009880.2; = p.E159K on NM_015264.2) | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.468); called by muse, mutect2
- LAMA2 | c.2558G>A p.G853E | Missense Mutation (SNP) | VAF 46/382 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- PCSK2 | c.323dup p.R109Afs*8 | Frame Shift Ins (INS) | VAF 98/317 reads (31%) | called by mutect2, pindel, varscan2
- SIDT1 | c.2474del p.P825Lfs*41 | Frame Shift Del (DEL) | VAF 34/235 reads (14%) | called by mutect2, pindel, varscan2
- SOX10 | c.666del p.M223Cfs*63 | Frame Shift Del (DEL) | VAF 16/93 reads (17%) | called by mutect2, pindel, varscan2
- UGT2B15 | c.861dup p.P288Tfs*4 | Frame Shift Ins (INS) | VAF 89/695 reads (13%) | called by mutect2, varscan2
- ZCCHC12 | c.819del p.D274Mfs*4 | Frame Shift Del (DEL) | VAF 88/174 reads (51%) | called by mutect2, pindel, varscan2
- ABRA | c.1077G>C p.L359= | Silent (SNP) | VAF 16/424 reads (4%) | catalogued as COSV61732781; called by muse, mutect2
- ACTN2 | c.744C>T p.Y248= | Silent (SNP) | VAF 84/162 reads (52%) | catalogued as rs749565466, COSV63976171, COSV63976770; ClinVar: likely benign; called by muse, mutect2, varscan2
- ARAP2 | c.4692G>C p.L1564= | Silent (SNP) | VAF 46/189 reads (24%) | catalogued as COSV58288515; called by muse, mutect2, varscan2
- ASB17 | c.453C>A p.L151= | Silent (SNP) | VAF 31/64 reads (48%) | catalogued as COSV52410924; called by muse, mutect2, varscan2
- ATP13A4 | c.1197C>T p.I399= | Silent (SNP) | VAF 335/1603 reads (21%) | catalogued as COSV55069135; called by muse, mutect2, varscan2
- BAZ2B | c.558A>G p.T186= | Silent (SNP) | VAF 50/269 reads (19%) | catalogued as COSV58603975; called by muse, mutect2, varscan2
- CBLIF | c.279C>G p.G93= | Silent (SNP) | VAF 24/210 reads (11%) | catalogued as COSV57239436; called by muse, mutect2, varscan2
- CDC40 | c.1044C>T p.L348= | Silent (SNP) | VAF 43/201 reads (21%) | catalogued as rs1448595846, COSV57009907; called by muse, mutect2, varscan2
- CDIN1 | c.735C>T p.V245= (on ENST00000437989; = p.V147= on NM_032499.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 32/231 reads (14%) | catalogued as COSV57712592; called by muse, mutect2, varscan2
- COLEC12 | c.1305C>T p.I435= | Silent (SNP) | VAF 12/138 reads (9%) | called by muse, mutect2
- CUBN | c.5112T>A p.P1704= | Silent (SNP) | VAF 17/110 reads (15%) | catalogued as COSV64719466; called by muse, mutect2, varscan2
- DDX53 | c.894G>T p.G298= | Silent (SNP) | VAF 91/168 reads (54%) | catalogued as COSV60069481; called by muse, mutect2, varscan2
- EMILIN2 | c.2223C>T p.V741= | Silent (SNP) | VAF 11/105 reads (10%) | called by muse, mutect2, varscan2
- FANK1 | c.240G>C p.L80= | Silent (SNP) | VAF 53/360 reads (15%) | catalogued as COSV64156746; called by muse, mutect2, varscan2
- FMNL1 | c.1980C>T p.F660= | Silent (SNP) | VAF 61/242 reads (25%) | catalogued as rs1168183383, COSV58957606; called by muse, mutect2, varscan2
- GARRE1 | c.123G>C p.L41= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as COSV55100031, COSV55100853, COSV55100888; called by muse, mutect2, varscan2
- HADHB | c.501G>A p.L167= | Silent (SNP) | VAF 25/204 reads (12%) | catalogued as COSV58546971; called by muse, mutect2, varscan2
- HEATR9 | c.585G>A p.E195= | Silent (SNP) | VAF 37/285 reads (13%) | catalogued as rs1212026467; called by muse, mutect2, varscan2
- HPX | c.867G>T p.R289= | Silent (SNP) | VAF 42/216 reads (19%) | catalogued as COSV56419823; called by muse, mutect2, varscan2
- HSPD1 | c.631T>C p.L211= | Silent (SNP) | VAF 20/81 reads (25%) | catalogued as COSV61444967; called by muse, mutect2, varscan2
- HTR1A | c.531C>T p.T177= | Silent (SNP) | VAF 113/408 reads (28%) | catalogued as COSV60500294, COSV60501450; called by muse, mutect2, varscan2
- KLHL24 | c.591T>C p.D197= | Silent (SNP) | VAF 54/1018 reads (5%) | catalogued as COSV54427072; called by muse, mutect2
- LIPI | c.1425A>C p.T475= | Silent (SNP) | VAF 65/540 reads (12%) | catalogued as COSV60712990; called by muse, mutect2, varscan2
- LRFN2 | c.1299C>T p.T433= | Silent (SNP) | VAF 14/84 reads (17%) | catalogued as COSV57829574; called by muse, mutect2, varscan2
- MACF1 | c.4062G>A p.L1354= | Silent (SNP) | VAF 30/198 reads (15%) | catalogued as COSV58382332; called by muse, mutect2, varscan2
- METTL3 | c.1146C>T p.D382= | Silent (SNP) | VAF 42/239 reads (18%) | catalogued as rs758697624, COSV52969841; called by muse, mutect2, varscan2
- MGAT5 | c.120T>G p.P40= | Silent (SNP) | VAF 11/64 reads (17%) | catalogued as COSV56097859; called by muse, mutect2, varscan2
- MINAR1 | c.2469G>A p.V823= | Silent (SNP) | VAF 50/122 reads (41%) | catalogued as COSV59584109; called by muse, mutect2, varscan2
- MTRF1 | c.117G>T p.L39= | Silent (SNP) | VAF 38/244 reads (16%) | catalogued as COSV53481715; called by muse, mutect2, varscan2
- MUC4 | c.15363C>A p.S5121= (on ENST00000463781 / NM_018406.7; = p.S885= on NM_004532.6) | Silent (SNP) | VAF 65/677 reads (10%) | catalogued as COSV57787925; called by muse, mutect2
- MYO3A | c.1180C>T p.L394= | Silent (SNP) | VAF 28/159 reads (18%) | catalogued as rs570749940, COSV56333286, COSV56336558; called by mutect2, varscan2
- MYO9A | c.4041C>T p.V1347= | Silent (SNP) | VAF 24/594 reads (4%) | called by muse, mutect2
- NBAS | c.4650C>A p.A1550= | Silent (SNP) | VAF 53/393 reads (13%) | catalogued as COSV55727025; called by muse, mutect2, varscan2
- NEB | c.6681G>A p.Q2227= | Silent (SNP) | VAF 55/294 reads (19%) | catalogued as COSV51429389; called by muse, mutect2, varscan2
- NPAS4 | c.1260T>C p.L420= | Silent (SNP) | VAF 39/238 reads (16%) | catalogued as rs1250458096, COSV60651166; called by muse, mutect2, varscan2
- OR2B11 | c.186C>A p.P62= | Silent (SNP) | VAF 359/710 reads (51%) | catalogued as COSV59509548, COSV59510563; called by muse, mutect2, varscan2
- OR56B1 | c.351G>T p.V117= | Silent (SNP) | VAF 45/112 reads (40%) | catalogued as rs760456044, COSV57723372; called by muse, mutect2, varscan2
- PCDHB13 | c.540G>T p.R180= | Silent (SNP) | VAF 34/138 reads (25%) | catalogued as COSV53398032; called by muse, mutect2, varscan2
- PDE1C | c.1338C>A p.T446= | Silent (SNP) | VAF 166/419 reads (40%) | catalogued as COSV58518114; called by muse, mutect2, varscan2
- PDYN | c.648C>A p.P216= | Silent (SNP) | VAF 80/267 reads (30%) | catalogued as COSV54102307; called by muse, mutect2, varscan2
- PHLDB2 | c.3295A>C p.R1099= (on ENST00000393925 / NM_001134439.2; = p.R1056= on NM_145753.2) | Silent (SNP) | VAF 17/81 reads (21%) | catalogued as COSV67312899; called by muse, mutect2, varscan2
- PHLPP1 | c.2601A>G p.L867= | Silent (SNP) | VAF 77/285 reads (27%) | catalogued as COSV53031732; called by muse, mutect2, varscan2
- PLRG1 | c.894G>T p.P298= | Silent (SNP) | VAF 69/236 reads (29%) | catalogued as COSV57423275, COSV57423963; called by muse, mutect2, varscan2
- PPARGC1A | c.1935G>A p.L645= | Silent (SNP) | VAF 20/254 reads (8%) | catalogued as rs780188940; called by muse, mutect2
- PTPRB | c.2529T>C p.N843= | Silent (SNP) | VAF 57/150 reads (38%) | catalogued as rs1414515778, COSV54244785; called by muse, mutect2, varscan2
- PXDNL | c.2028G>A p.V676= | Silent (SNP) | VAF 13/19 reads (68%) | catalogued as COSV62491290; called by muse, mutect2, varscan2
- RTP5 | c.603C>T p.V201= | Silent (SNP) | VAF 4/9 reads (44%) | catalogued as COSV58320737; called by mutect2, varscan2
- SLC16A10 | c.555G>A p.Q185= | Silent (SNP) | VAF 16/142 reads (11%) | catalogued as COSV64354696; called by muse, mutect2, varscan2
- SNTB1 | c.186C>A p.T62= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as COSV101179915; called by muse, mutect2, varscan2
- SOX1 | c.273C>A p.V91= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV58379524; called by muse, mutect2, varscan2
- ST8SIA3 | c.202C>T p.L68= | Silent (SNP) | VAF 38/200 reads (19%) | catalogued as COSV104407574, COSV60654515; called by muse, mutect2, varscan2
- TBC1D4 | c.1413C>G p.L471= | Silent (SNP) | VAF 30/184 reads (16%) | catalogued as COSV66489938; called by muse, mutect2, varscan2
- TMEM267 | c.534C>T p.F178= | Silent (SNP) | VAF 157/504 reads (31%) | catalogued as COSV67992881; called by muse, mutect2, varscan2
- TNR | c.4041C>T p.L1347= | Silent (SNP) | VAF 153/1091 reads (14%) | catalogued as COSV54894979; called by muse, mutect2, varscan2
- TPRG1 | c.297G>A p.L99= | Silent (SNP) | VAF 230/511 reads (45%) | catalogued as rs780355022, COSV61466014; called by muse, mutect2, varscan2
- TTN | c.12213A>T p.P4071= (on ENST00000591111; = p.P4025= on NM_003319.4) | Silent (SNP) | VAF 16/81 reads (20%) | catalogued as COSV60153447; called by mutect2, varscan2
- USP7 | c.2655C>T p.I885= | Silent (SNP) | VAF 36/203 reads (18%) | catalogued as COSV61215600; called by muse, mutect2, varscan2
- ANKRD20A5P | n.162G>T | RNA (SNP) | VAF 6/19 reads (32%) | called by muse, mutect2, varscan2
- DDX41 | c.*556G>T | 3'UTR (SNP) | VAF 48/138 reads (35%) | catalogued as COSV57252178, COSV57253026; called by muse, mutect2, varscan2
- IGF2BP2 | c.240-18395G>A | Intron (SNP) | VAF 26/488 reads (5%) | catalogued as rs528345402, COSV56211723; called by muse, mutect2
- ZNF658B | n.868C>T | RNA (SNP) | VAF 91/563 reads (16%) | catalogued as rs1346303579; called by muse, mutect2, varscan2
